Somatic mutation profile of tumor specimen MP2PRT-PAPDDA-TMP1-A (aliquot MP2PRT-PAPDDA-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPDDA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,685 days).
Specimen MP2PRT-PAPDDA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02ffd4c2-b77d-403c-9ff4-f1ed570580b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPDDA-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPDDA-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01817ed3-26bd-4175-aec1-3720d00b2224

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Frame Shift Ins 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 52/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs397507544, CM044932, COSV61005111; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRIK4 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.947); catalogued as rs765839305; called by muse, mutect2, varscan2
- IL12RB2 | c.2334G>T p.K778N | Missense Mutation (SNP) | VAF 158/393 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.598); catalogued as rs1217246565; called by muse, mutect2, varscan2
- KDM6B | c.3532C>T p.R1178W | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs779500605; called by muse, mutect2, varscan2
- KIAA1217 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 81/456 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs764141082; called by muse, mutect2, varscan2
- TCEAL6 | c.357C>G p.D119E | Missense Mutation (SNP) | VAF 484/498 reads (97%) | SIFT tolerated (1); PolyPhen possibly damaging (0.865); catalogued as COSV101036025; called by muse, varscan2
- TIMM44 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs766115379; called by muse, mutect2, varscan2
- WLS | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202076524; called by muse, mutect2, varscan2
- ARHGAP23 | c.1216T>C p.S406P | Missense Mutation (SNP) | VAF 19/636 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ASXL1 | c.1647_1648insCCCC p.N550Pfs*5 | Frame Shift Ins (INS) | VAF 79/156 reads (51%) | called by pindel, varscan2
- ASXL1 | c.1849dup p.I617Nfs*2 | Frame Shift Ins (INS) | VAF 65/232 reads (28%) | called by mutect2, pindel, varscan2
- DCAF8L2 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 178/368 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM81A | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLXND1 | c.881_882delinsCCGGGGC p.Q294Pfs*169 | Frame Shift Ins (INS) | VAF 162/424 reads (38%) | called by pindel, varscan2*
- LAMC3 | c.3042G>A p.P1014= | Silent (SNP) | VAF 68/234 reads (29%) | catalogued as rs150155891; called by muse, mutect2, varscan2
- MINK1 | c.1326G>T p.R442= | Silent (SNP) | VAF 96/318 reads (30%) | called by muse, varscan2
- OTOG | c.7050C>T p.Y2350= | Silent (SNP) | VAF 149/323 reads (46%) | catalogued as rs559006203; called by muse, mutect2, varscan2
